Surgical pathology report (de-identified scan), TCGA case TCGA-ZF-A9R2, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Sheffield, specimen TCGA-ZF-A9R2-01A (Primary Tumor).

[page 1 of 2]
Histopathology

Specimen Comments

SPECIMEN

- A. Distal right ureteric resection margin
- B. Right obturator node
- C. Left obturator node
- D. Right external iliac
- E. Right obturator node (2)
- F. Right internal iliac
- G. Left external iliac node
- H. Left obturator node (2)
- I. Left ureteric resection margin
- J. Proximal right ureteric resection margin
- K. Bladder and prostate

IAD-0-3
Carcinoma, urothelial papillary 8/30/13
Site: Bladder NOS 0679
JAS/2/14

CLINICAL DETAILS

MIBC with bilateral hydronephrosis and lymph nodes. Cystoprostatectomy.

MACROSCOPY

- A. Cream coloured tissue measuring up to 6 mm in maximum dimension.
- B. Fatty tissue measuring 53 x 20 x 14 mm, containing one lymph node measuring 25 mm.
- C. Fatty tissue measuring 37 x 27 x 10 mm, containing one lymph node measuring up to 13 mm.
- D. Fatty tissue measuring 45 x 22 x 15 mm, containing one lymph node measuring up to 40 mm.
- E. Fatty tissue measuring 47 x 35 x 15 mm, containing one lymph node measuring up to 27 mm.
- F. Fatty tissue measuring 38 x 32 x 12 mm, containing one lymph node measuring up to 10 mm.
- G. Two pieces of fatty tissue measuring 28 and 24 mm respectively. Two lymph nodes are identified measuring 8 and 14 mm.
- H. Fatty tissue measuring 50 x 35 x 12 mm, containing one lymph node measuring up to 40 mm.
- I. Grey tissue measuring 8 mm.
- J. Grey tissue measuring 10 mm in maximum dimension.
- K. Radical cystoprostatectomy measuring 95 mm superior inferior x 87 mm transverse x 80 mm anterior posterior. The prostate measures 30 mm superior inferior x 38 mm transverse x 32 mm anterior posterior. The bladder measures 85 mm superior inferior x 75 mm transverse x 62 mm anterior posterior. There is peritoneum measuring up to 60 mm to the dome of the bladder. Within the bladder there is extensive tumour covering the left and right lateral walls, anterior and posterior wall and the dome. The tumour appears to invade through the bladder wall at the left lateral side. There are no peritoneal nodules of tumour. No lymph nodes are identified. 1 = Urethral resection margin, 2 = Left lobe prostate, 3 = Right lobe prostate, 4 = Trigone, 5 = Dome, 6 = Posterior wall, 7 = Left lateral wall ? extraneural extension, 8 = Anterior ? extraneural extension, 9 = Right lateral wall, 10-12 = Tumour

MICROSCOPY

- A. This is normal urothelial mucosa.
- B. This is one lymph node, without neoplasia.
- C. This is one lymph node, without neoplasia.
- D. This is one lymph node, without neoplasia.
- E. This is one lymph node, without neoplasia.
- F. This is connective tissue, no lymph node is identified.
- G. These are two lymph nodes. No neoplasia is identified.
- H. This is one lymph node. No neoplasia is identified.
- I. This is urothelial mucosa. There is no evidence of neoplasia or dysplasia.
- J. This is ureteric tissue, which is denuded of epithelium. No evidence of

[page 2 of 2]
neoplasia is identified.

K. This is bladder and prostate. Anteriorly within the bladder, there is a urothelial carcinoma showing papillary and invasive areas. The tumour is mostly moderately differentiated but there is a focus of poorly differentiated tumour which shows extension into the outer 1/3 of the muscularis. Lymphovascular invasion is seen. The circumferential resection margin is clear of tumour. The prostate and urethral resection margins are normal.

Summary:

Radical cystoprostatectomy with pelvic lymph nodes -

High grade urothelial carcinoma of the bladder.

TNM (7th Edition 2009): pT2b, pN0, R0

Ref:

Pathologists -

Update 3/21/14

Patient was contacted by TSS and
Verified they received surgery - only for their
prior malignancy. OK to ship.

Subsequent information indicates
pt. had unknown treatment for
prior malignancy. Not shipped -
3/19/14 will annotate at B9

Source: NCI Genomic Data Commons file ab81340a-25d9-4747-9adf-459b67f47f73 (TCGA-ZF-A9R2.B5679648-237C-4F65-87BB-CD92D0C53393.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).